Somatic mutation profile of tumor specimen TCGA-Z6-A9VB-01A (aliquot TCGA-Z6-A9VB-01A-21D-A37C-09) from TCGA case TCGA-Z6-A9VB, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.3 years (19,470 days).
Specimen TCGA-Z6-A9VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6a7c0b1-55ac-479d-a065-478194a115d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z6-A9VB-10A (Blood Derived Normal), aliquot TCGA-Z6-A9VB-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8286ee5e-aa74-4165-b7ad-c7aeffd85e29

The open-access MAF lists 104 somatic variants for this specimen: 72 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 29, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, Frame Shift Ins 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.2234C>T p.T745M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs28939720, CM131121, CM992150; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1273A>G p.M425V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104893817, CM060084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.326T>C p.F109S | Missense Mutation (SNP) | VAF 42/65 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796722, COSV52725602, COSV52838438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750800733, COSV54388911; called by muse, mutect2, varscan2
- AP002512.3 | c.1094G>T p.R365I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs758257323; called by muse, mutect2, varscan2
- ARHGEF7 | c.1841C>T p.A614V (on ENST00000375741 / NM_001113511.2; = p.A436V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs750833153, COSV54541344; called by muse, mutect2, varscan2
- CCDC18 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1384785300; called by muse, mutect2, varscan2
- CNTNAP5 | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV70474272, COSV70513309; called by muse, mutect2, varscan2
- CREB3L1 | c.1518C>A p.H506Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs773657140; called by mutect2, varscan2
- CYP2W1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs1307551632; called by muse, mutect2, varscan2
- DMBT1 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs539964635; called by muse, mutect2, varscan2
- FGD6 | c.4117G>A p.A1373T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173260579, COSV59691985; called by muse, mutect2, varscan2
- FPR2 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs373596683; called by muse, mutect2, varscan2
- GPR158 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV66275933; called by muse, mutect2, varscan2
- HECW2 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055884939, COSV53649636; called by muse, mutect2
- IFT140 | c.2611C>A p.R871S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1511882, COSV54151796; called by muse, mutect2, varscan2
- MATK | c.952A>G p.T318A (on ENST00000310132 / NM_139355.3; = p.T319A on NM_002378.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs777199822; called by muse, mutect2
- MYH14 | c.3965G>A p.R1322H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs727504915; ClinVar: uncertain significance; called by muse, mutect2
- NCAN | c.2024C>T p.T675I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1217446839, COSV104384730, COSV99386972; called by muse, mutect2, varscan2
- OR6Y1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0.077); catalogued as COSV56929141; called by muse, mutect2, varscan2
- PLEC | c.3997G>A p.D1333N (on ENST00000322810 / NM_201380.4; = p.D1223N on NM_000445.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs782221430; called by muse, mutect2
- RRS1 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1169844316; called by muse, mutect2, varscan2
- SAGE1 | c.2201C>A p.P734H | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61018235; called by muse, mutect2, varscan2
- SALL1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs757169483; called by muse, mutect2, varscan2
- SERPINA7 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs182605024; called by muse, varscan2
- TNFRSF8 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV55797494; called by muse, mutect2, varscan2
- TRIO | c.4921G>A p.A1641T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs775980433; called by muse, mutect2, varscan2
- UGT2B17 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 27/39 reads (69%) | catalogued as rs267600213, COSV58500918; called by muse, mutect2, varscan2
- XKR4 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59312916; called by muse, mutect2, varscan2
- ZNF175 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.076); catalogued as COSV51796133, COSV51796687; called by muse, mutect2, varscan2
- AKR1C2 | c.251del p.K84Sfs*20 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- ANK3 | c.8222del p.D2741Vfs*31 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- CCDC7 | c.3139A>G p.I1047V | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CDCA7L | c.872del p.A291Vfs*43 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- CLK1 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CNTNAP5 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- COL22A1 | c.1304G>T p.C435F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DPEP3 | c.1182A>T p.Q394H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- ELK3 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- FPR2 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KALRN | c.2000A>G p.D667G | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNH1 | c.2525A>T p.D842V (on ENST00000271751 / NM_172362.3; = p.D815V on NM_002238.4) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KRT24 | c.861G>T p.M287I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP3K10 | c.846A>T p.K282N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MB21D2 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MEF2C | c.751C>A p.R251S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MUC2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- NRXN3 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NVL | c.690G>T p.R230S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NYAP2 | c.1608G>T p.E536D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2V2 | c.432G>C p.Q144H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- OR2W1 | c.893A>T p.K298M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, varscan2
- P4HA1 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- P4HB | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PBX1 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDS5A | c.840A>C p.L280F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZD8 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- PITPNM1 | c.3516_3537delinsT p.G1173_S1179del | In Frame Del (DEL) | VAF 13/62 reads (21%) | called by pindel, varscan2*
- PMS2 | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRB4 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- RIPOR2 | c.1336C>A p.H446N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- RLF | c.1870T>A p.S624T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9A9 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- SLIT2 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTA1 | c.1959dup p.A654Cfs*3 | Frame Shift Ins (INS) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- ST6GALNAC1 | c.132G>A p.R44= | Splice Region (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- TMED9 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TMEM199 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.112); called by mutect2, varscan2
- TRIP11 | c.3721C>A p.Q1241K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- TUBB1 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR18 | c.1279A>G p.I427V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ZDHHC13 | c.703A>C p.K235Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ADAM32 | c.1311C>T p.C437= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV65954200; called by muse, mutect2, varscan2
- AQP10 | c.642C>T p.N214= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs867427480, COSV61474556; called by muse, mutect2, varscan2
- BACE2 | c.1212G>A p.A404= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs764727127; called by muse, mutect2, varscan2
- COL15A1 | c.96G>T p.A32= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- CSMD3 | c.9999A>T p.A3333= (on ENST00000297405 / NM_001363185.1; = p.A3164= on NM_052900.3) | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV52290025; called by muse, mutect2, varscan2
- CST1 | c.210A>G p.V70= | Silent (SNP) | VAF 43/54 reads (80%) | called by muse, mutect2, varscan2
- FAM90A1 | c.339G>A p.Q113= | Silent (SNP) | VAF 84/169 reads (50%) | catalogued as COSV56711903; called by muse, mutect2, varscan2
- FASN | c.6870C>T p.I2290= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs967248602; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR12 | c.450G>A p.S150= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs772800273, COSV101198038, COSV67344432; called by muse, mutect2, varscan2
- GRM8 | c.1857C>T p.R619= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58805752, COSV58854595; called by muse, mutect2
- GSTK1 | c.372C>T p.R124= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1189386499, COSV100621811; called by muse, mutect2, varscan2
- KRT82 | c.33G>A p.R11= | Silent (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2
- MAPT | c.1314G>A p.P438= (on ENST00000262410 / NM_001377265.1; = p.P363= on NM_016835.4) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs781182606; called by muse, mutect2, varscan2
- MINAR1 | c.1509C>T p.T503= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100548900; called by muse, mutect2, varscan2
- MTNR1A | c.465G>A p.T155= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs767642752; called by muse, mutect2, varscan2
- MUC4 | c.16134C>T p.G5378= (on ENST00000463781 / NM_018406.7; = p.G1142= on NM_004532.6) | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs199920657; called by muse, mutect2, varscan2
- NANS | c.1014T>A p.T338= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- NEB | c.11721G>A p.T3907= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs531949723; called by muse, mutect2, varscan2
- NKPD1 | c.1395C>T p.Y465= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- PFAS | c.411G>T p.V137= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.174C>G p.A58= | Silent (SNP) | VAF 46/386 reads (12%) | called by muse, mutect2, varscan2
- PRKD2 | c.757C>T p.L253= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2
- RIMBP2 | c.1302C>T p.A434= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as rs769245689, COSV99900029; called by muse, mutect2, varscan2
- SLC25A40 | c.528C>T p.Y176= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs768592461; called by muse, mutect2, varscan2
- STT3B | c.1803A>G p.V601= | Silent (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- TGM1 | c.942C>T p.G314= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- TMEM67 | c.2532C>T p.D844= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs771098362; called by muse, mutect2, varscan2
- VPS13D | c.2724T>A p.T908= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- ZNF579 | c.976C>T p.L326= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- DNAH1 | c.9363+70G>A | Intron (SNP) | VAF 12/27 reads (44%) | catalogued as rs371140016; called by muse, mutect2, varscan2
- TMEM183B | n.602C>A | RNA (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.10361-5311G>T | Intron (SNP) | VAF 48/66 reads (73%) | catalogued as COSV100595491; called by muse, mutect2, varscan2
